Surgical pathology report (de-identified scan), TCGA case TCGA-33-A4WN, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-A4WN-01A (Primary Tumor).

[page 1 of 7]
pg 1/7

=====

INTERPRETATION AND DIAGNOSIS:

1. LUNG, RIGHT UPPER LOBE AND SUPERIOR SEGMENT OF RIGHT LOWER LOBE (LOBECTOMY AND SEGMENTECTOMY): INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (4.5 CM), STAGE pT2a N0. CARCINOMA IN-SITU WAS PRESENT IN THE RIGHT MAIN BRONCHUS WITHIN 2.0 CM OF THE CARINA. THE FINAL PROXIMAL SURGICAL BRONCHIAL MARGINS ARE NEGATIVE FOR TUMOR OR CARCINOMA IN-SITU. NO LYMPH NODE METASTASES WERE IDENTIFIED. TUMOR EXTENDS FROM THE UPPER LOBE ACROSS THE FISSURE INTO THE SUPERIOR SEGMENT OF THE LOWER LOBE BUT THE LOWER LOBE MARGINS ARE NEGATIVE FOR TUMOR. SEE SYNOPTIC REPORT FOR DETAILS.

SPECIMEN TYPE: LOBECTOMY

TUMOR SITE: RIGHT

HISTOLOGIC TYPE: SQUAMOUS CELL CARCINOMA

TUMOR SIZE: GREATEST DIMENSION: 4.5 CM

HISTOLOGIC GRADE: G2: MODERATELY DIFFERENTIATED

LYMPH NODES (INCLUDES ALL PARTS): ALL THIRTY-SEVEN (37) LYMPH NODES ARE NEGATIVE FOR TUMOR (INCLUDES PARTS 1-5)

DIRECT EXTENSION OF TUMOR: VISCERAL PLEURA (INVASION ACROSS FISSURE INTO SUPERIOR SEGMENT OF LOWER LOBE)

EXTENT OF INVASION (7TH EDITION AJCC)

PRIMARY TUMOR:

pT2a: TUMOR MORE THAN 3.0 CM, BUT 5.0 CM OR LESS

REGIONAL LYMPH NODES:

pT0: NO REGIONAL LYMPH NODE METASTASIS

DISTANT METASTASIS:

pMx: CANNOT BE ASSESSED

MARGINS: MARGINS UNINVOLVED BY INVASIVE CARCINOMA

DISTANCE OF INVASIVE CARCINOMA FROM NEAREST

MARGIN: 7.0 MM

SPECIFY MARGIN: RIGHT LOWER LOBE SUPERIOR SEGMENT

VENOUS/ARTERIAL (LARGE VESSEL) INVASION: ABSENT

LYMPHATIC (SMALL VESSEL) INVASION: ABSENT

(Continued on next page.)

1CD-0-3
carcinoma, squamous cell, NOS
8070/3
Site: lung, upper lobe c34.1

mw
10/27/12

[page 2 of 7]
=====

ADDITIONAL PATHOLOGIC FINDINGS:

EMPHYSEMATOUS CHANGES, RESPIRATORY BRONCHIOLITIS.
CARCINOMA IN-SITU (SQUAMOUS) INVOLVING MAINSTEM BRONCHUS
WITHIN 0.5 CM OF CARINA (NOT THE FINAL MARGIN)

2. RIGHT MAINSTEM BRONCHUS (EXCISION): NEGATIVE FOR CARCINOMA. SEE
SYNOPTIC REPORT.

3. STATION 7 LYMPH NODES (EXCISION): FIVE (5) LYMPH NODES AND
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

4. STATION 4R LYMPH NODES (EXCISION): ONE (1) LYMPH NODE AND
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

5. STATION 10R LYMPH NODE (EXCISION): FOUR (4) LYMPH NODES AND
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

*Electronic signature

=====

Pre-Operative Diagnosis:

RUL LUNG CANCER INVADING SUPERIOR SEGMENT

GROSS DESCRIPTION

(Continued on next page.)

[page 3 of 7]
=====

PART #1: FS: RIGHT UPPER LOBE AND RIGHT LOWER LOBE SUPERIOR SEGMENT
Resident Pathologist:

FROZEN SECTION DIAGNOSIS:
Staff Pathologist:
Other Pathologists /

1) FS: RUL AND RLL SUPERIOR SEGMENT:

A) RIGHT MAINSTEM BRONCHIAL MARGIN: FOCAL SCC IN SITU, MICROSCOPIC
INVASION CAN NOT BE EXCLUDED.

B) RIGHT BRONCHUS INTERMEDIUS MARGIN: NEGATIVE FOR TUMOR.

C) RLL SUPERIOR SEGMENT MARGIN: NEGATIVE FOR TUMOR.

DIAGNOSIS CONFIRMED WITH

THE SPECIMEN IS RECEIVED FOR FROZEN SECTION DIAGNOSIS, LABELED WITH
THE PATIENT'S NAME, [REDACTED] AND DESIGNATED RIGHT UPPER LOBE
AND RIGHT LOWER LOBE SUPERIOR SEGMENT. THE SPECIMEN CONSISTS OF A
449 GM RIGHT SUPERIOR LOBECTOMY AND RIGHT INFERIOR LOBE WEDGE
RESECTION MEASURING 20.0 X 15.0 X 7.0 CM. THE PLEURAL SURFACE
APPEARS SOMEWHAT MOTTLED. TWO AREAS OF THE PLEURAL APPEAR PUCKERED
(1.8 CM AND 2.0 CM IN GREATEST DIMENSION). THESE AREAS HAVE BEEN
INKED BLACK AND REPRESENTATIVE SECTIONS MOST CONCERNING FOR PLEURAL
INVOLVEMENT BY TUMOR SUBMITTED. TWO STAPLE LINES ARE PRESENT IN THE
LUNG; THE FIRST MEASURING 12.0 CM, SUPERIOR TO INFERIOR, ALONG THE
POSTERIOR ASPECT OF THE RIGHT SUPERIOR LOBE; THE SECOND STAPLE LINE
IS 9.0 CM, LATERAL TO MEDIAL, ALONG THE POSTERIOR ASPECT OF THE RIGHT
INFERIOR LOBE. THESE STAPLE LINES ARE CAREFULLY REMOVED AND THE
UNDERLYING LUNG PARENCHYMA INKED ORANGE. THREE LARGE VESSELS THAT
HAVE BEEN STAPLED CLOSED ARE IDENTIFIED AT THE HILUM OF THE LUNG. THE
STAPLES ARE REMOVED AND SHAVE SECTIONS ARE SUBMITTED OF EACH VESSEL.
THE RIGHT MAIN BRONCHUS AND BRONCHUS INTERMEDIUS ARE IDENTIFIED AND
SHAVE MARGINS OF EACH ARE SUBMITTED FOR FROZEN SECTION DIAGNOSES. A
PERPENDICULAR SECTION OF THE RIGHT INFERIOR LOBE AT THE STAPLE LINE
IN RELATION TO TUMOR WAS ALSO SUBMITTED FOR FROZEN SECTION DIAGNOSIS.
THE SPECIMEN IS THEN SECTIONED ALONG THE AXIS OF THE MAJOR AIRWAYS TO
REVEAL A 4.5 CM MASS THAT GROSSLY APPEARS TO ARISE FROM THE RIGHT
SUPERIOR LOBE ADJACENT TO LARGE AIRWAYS. THE MASS IS 2.2 FROM THE

(Continued on next page.)

[page 4 of 7]
=====

=====

VASCULAR MARGINS AND 1.5 CM FROM THE CLOSEST ASPECT OF THE BRONCHIAL MARGINS. MULTIPLE ENLARGED HILAR LYMPH NODES ARE IDENTIFIED RANGING IN SIZE FROM 0.5 CM TO 1.8 CM AND WERE SUBMITTED. THE SPECIMEN WAS NEXT SECTIONED ALONG THE AXIS OF MAJOR AIRWAYS NOT IN PROXIMITY TO THE MASS AND AWAY FROM THE MASS. REPRESENTATIVE SECTION OF THESE UNINVOLVED AIRWAYS WERE SUBMITTED. THE MASS AND SURROUNDING LUNG TISSUE WAS THEN SERIALLLY SECTIONED IN THE TRANSVERSE PLAIN FROM SUPERIOR TO INFERIOR TO REVEAL THAT THE TUMOR APPEARS TO EXTEND FROM THE RIGHT SUPERIOR LOBE INTO THE RIGHT INFERIOR LOBE. SERIAL SECTIONING THROUGH THE REMAINING LUNG TISSUE IDENTIFIES A REGION SUSPICIOUS OF TUMOR INVASION TOWARDS THE LUNG PLEURA. HOWEVER, THE TUMOR APPEARS GROSSLY TO BE CONTAINED WITHIN THE VISCERAL PLEURA. REPRESENTATIVE SECTIONS OF THE TWO SEPERATE AREAS SUSPICIOUS FOR TUMOR INVOLVEMENT OF PLEURA WERE SUBMITTED. THE REMAINING LUNG WAS SERIALLY SECTION TO REVEAL NO OTHER MASSES OR LESIONS. THE REMAINING LUNG TISSUE APPEARS SOMEWHAT CONGESTED. IN TOTAL, APPROXIMATELY 95% OF THE TUMOR MASS IS SUBMITTED AND APPROXIMATELY 15% OF THE TOTAL SPECIMEN IS SUBMITTED.

1 - 1 (RT MAIN BRONCHUS)
1 - 1 (RT BRONCHUS INTERMEDIUS)
1 - - 1 (RT INFERIOR LOBE MARGIN)
1 - A - 3 (VASC MARGINS)
1 - B - 2 (1 LN BISECTED)
1 - C - 2 (1 LN BISECTED)
1 - D - M (4 LN)
1 - E - 3 (1 LN)
1 - F - 4 (4 LN)
1 - G - 2 (1 LN)
1 - H - 1 (1 LN)
1 - I - 3 (UNINVOLVED LARGE AIRWAY AND CROSS SECTION)
1 - J - 3 (UNINVOLVED LARGE AIRWAY AND CROSS SECTION)
8 -K-R- 1 (SERIAL SECTIONS THRU TUMOR FROM PROX-DISTAL)
2 -S-T- 1 (TUMOR WITH PLEURAL INVOLVEMENT, TWO SEPERATE LOCATIONS)
1 - U - 1 (TUMOR WITH EXTENSION FROM 1 LOBE TO ANOTHER)
2 -V-W- 1 (TUMOR IN RELATION TO INFERIOR LOBE LUNG MARGIN)
2 -X-Y- 1 (REP UNINVOLVED LUNG)
28 -T- M

(Continued on next page.)

[page 5 of 7]
pg 5/7

=====

PART #2: FS: RIGHT MAIN STEM BRONCHUS
Resident Pathologist:

FROZEN SECTION DIAGNOSIS:

Staff Pathologist:

Other Pathologists

2) RIGHT MAIN STEM BRONCHUS: NEGATIVE FOR CARCINOMA.

DIAGNOSIS CONFIRMED WITH

THE SPECIMEN IS RECEIVED FRESH FOR FROZEN SECTION DIAGNOSIS, LABELED WITH THE PATIENT'S NAME, [REDACTED] AND DESIGNATED RIGHT MAIN STEM BRONCHUS. THE SPECIMEN CONSISTS OF A PORTION OF LARGE AIRWAY MEASURING 2.0 CM IN DIAMETER AND 0.3 CM IN LENGTH. THE MAJORITY OF THE SPECIMEN WAS SUBMITTED FOR FROZEN SECTION DIAGNOSIS. A STITCH WAS PRESENT ON ONE ASPECT OF THE TISSUE DESIGNATING THE TRUE MARGIN OF THE SPECIMEN. NO GROSSLY APPRECIABLE MASSES OR LESIONS WERE APPARENT ON THIS PIECE OF TISSUE. THE REMAINDER OF THE TISSUE NOT USED FOR FROZEN SECTION DIAGNOSIS WAS SUBMITTED FOR STANDARD HISTOLOGIC ASSESSMENT.

1 -FSC- 1

1 - A - 1

2 - T - 2 (RT MAIN STEM BRONCHUS)

(Continued on next page.)

[page 6 of 7]
pg 6/7

=====

PART #3: STATION 7
Resident Pathologist

THE SPECIMEN IS RECEIVED IN FORMALIN, LABELED WITH THE PATIENT'S NAME, [REDACTED] AND DESIGNATED STATION 7. THE SPECIMEN CONSISTS OF ONE FRAGMENT OF DARK-RED-PURPLE LYMPHOID TISSUE MEASURING 3.0 X 1.5 X 1.0 CM. IN ASSOCIATION TO THE TISSUE ARE APPROXIMATELY FOUR LYMPH NODES RANGING IN SIZE FROM 0.6 CM TO 0.2 CM. THE LARGER FRAGMENT IS CAREFULLY BISECTED AND SUBMITTED ENTIRELY. ADDITIONALLY, THE ENTIRETY OF THE TOTAL SPECIMEN IS SUBMITTED.

- 1 - A - M (ASSOCIATION LYMPHOID TISSUE)
- 4 -B-E- 1 (SECTIONS THRU LARGER FRAGMENT OF LYMPHOID TISSUE)
- 5 - T - M

PART #4: 4R LYMPH NODE
Resident Pathologist:

THE SPECIMEN IS RECEIVED IN FORMALIN, LABELED WITH THE PATIENT'S NAME, [REDACTED] AND DESIGNATED 4R LYMPH NODE. THE SPECIMEN CONSISTS OF ONE FRAGMENT OF LYMPHOID TISSUE IN ASSOCIATION WITH FIBROADIPOSE TISSUE MEASURING 2.0 X 1.8 X 0.7 CM. THE ENTIRETY OF THE SPECIMEN IS CAREFULLY BISECTED AND ENTIRELY SUBMITTED.

- 2 -A-B- M (4R LN)
- 2 - T - M

(Continued on next page.)

[page 7 of 7]
pg 7/7

=====

=====

PART #5: 10R LYMPH NODE
Resident Pathologist:

THE SPECIMEN IS RECEIVED IN FORMALIN, LABELED WITH THE PATIENT'S
NAME, [REDACTED] AND DESIGNATED 10R LYMPH NODE. THE SPECIMEN
CONSISTS OF FOUR SUSPECTED LYMPH NODES RANGING IN SIZE FROM 0.3 CM TO
0.7 CM. THE ENTIRETY OF THE SPECIMEN IS SUBMITTED.

1 - A - M (10R LN)
1 - T - M

Other Surgical Pathology Specimens known to the computer: [REDACTED]
[REDACTED]

=====

(End of Report)

Source: NCI Genomic Data Commons file 271c834f-51a0-42e2-bd22-ec7dafc7ec64 (TCGA-33-A4WN.D4BD5AF3-DDC8-4724-A9E7-F54F5BDB9826.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).